Somatic mutation profile of tumor specimen 0DFF72 from CCDI case PBBRPW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Sarcoma, NOS; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 12.2 years (4,439 days).
Specimen 0DFF72: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74eb15c4-8437-4395-9811-3f4fe05913f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DFF6Z (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0650d9b8-fa52-4100-a2ec-c9245ae9c08b

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Intron 3, Frame Shift Del 3, Silent 2, 5'UTR 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.351A>C p.K117N | Missense Mutation (SNP) | VAF 473/1234 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs770248150, COSV55504752, COSV55545304; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ATP6V0A4 | c.1325G>A p.W442* | Nonsense Mutation (SNP) | VAF 323/730 reads (44%) | catalogued as COSV59475313, COSV59477512; called by muse, mutect2, varscan2
- CLDN16 | c.176G>A p.R59H | Missense Mutation (SNP) | VAF 529/1423 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs762831659, COSV53227188; called by muse, mutect2, varscan2
- CSMD2 | c.1880C>T p.P627L | Missense Mutation (SNP) | VAF 164/421 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as COSV53885317; called by muse, mutect2, varscan2
- DICER1 | c.5113G>A p.E1705K | Missense Mutation (SNP) | VAF 203/304 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58615252, COSV58618257; called by muse, mutect2, varscan2
- NPAP1 | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 230/570 reads (40%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.847); catalogued as rs1209551646, COSV61505168, COSV61507605; called by muse, mutect2, varscan2
- SLCO2A1 | c.1906G>A p.V636M | Missense Mutation (SNP) | VAF 233/668 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.401); catalogued as rs764309379, COSV100188952; called by muse, mutect2, varscan2
- TENM4 | c.7549A>G p.K2517E | Missense Mutation (SNP) | VAF 389/921 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.018); catalogued as rs757694233; called by muse, mutect2, varscan2
- FER1L6 | c.3757G>T p.G1253W | Missense Mutation (SNP) | VAF 234/1391 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.315); called by muse, mutect2, varscan2
- H2AZ1 | c.242G>A p.R81H | Missense Mutation (SNP) | VAF 446/1220 reads (37%) | SIFT tolerated (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- KIF7 | c.836del p.L279Pfs*43 | Frame Shift Del (DEL) | VAF 134/320 reads (42%) | called by mutect2, varscan2
- MUC16 | c.23136del p.S7713Lfs*5 | Frame Shift Del (DEL) | VAF 258/658 reads (39%) | called by mutect2, varscan2
- PLXNA2 | c.1486T>C p.Y496H | Missense Mutation (SNP) | VAF 150/730 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RBM15 | c.1666C>G p.R556G | Missense Mutation (SNP) | VAF 148/329 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- SCGB1C2 | c.141G>T p.E47D | Missense Mutation (SNP) | VAF 160/789 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TTLL11 | c.1125del p.C376Afs*22 | Frame Shift Del (DEL) | VAF 159/439 reads (36%) | called by mutect2, varscan2
- ZNF800 | c.1698T>G p.D566E | Missense Mutation (SNP) | VAF 536/1347 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KRT19 | c.747G>T p.L249= | Silent (SNP) | VAF 326/845 reads (39%) | called by muse, mutect2, varscan2
- OPN4 | c.522C>T p.R174= | Silent (SNP) | VAF 404/950 reads (43%) | catalogued as COSV54119553; called by muse, mutect2, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 11/277 reads (4%) | called by muse, mutect2
- PDIA5 | c.-47G>C | 5'UTR (SNP) | VAF 137/281 reads (49%) | called by muse, mutect2, varscan2
- PXK | c.102+417A>C | Intron (SNP) | VAF 208/460 reads (45%) | catalogued as rs1426321536; called by muse, mutect2, varscan2
- TRIML2 | c.621+9C>A | Intron (SNP) | VAF 284/726 reads (39%) | called by muse, mutect2, varscan2
